Somatic mutation profile of tumor specimen TCGA-BP-5169-01A (aliquot TCGA-BP-5169-01A-01D-1429-08) from TCGA case TCGA-BP-5169, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G4; Age at diagnosis: 70.1 years (25,615 days).
Specimen TCGA-BP-5169-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 910188a4-559b-47bb-863e-5d97b980ab02.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BP-5169-11A (Solid Tissue Normal), aliquot TCGA-BP-5169-11A-01D-1429-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/06406535-2392-46b7-b579-75ecd354e403

The open-access MAF lists 55 somatic variants for this specimen: 40 protein-altering or splice-affecting, 10 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 32, Silent 10, Nonsense Mutation 3, Frame Shift Del 3, Splice Site 2, 5'Flank 2, Intron 1, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VHL | c.343C>T p.H115Y | Missense Mutation (SNP) | VAF 53/271 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs5030811, CD141839, CM961423, CM982005, COSV56545369, COSV56546151, COSV56556158, COSV56571206; called by muse, mutect2, varscan2
- ARHGAP35 | c.2257C>T p.Q753* | Nonsense Mutation (SNP) | VAF 18/101 reads (18%) | catalogued as COSV68331214; called by muse, mutect2, varscan2
- BIRC6 | c.5143G>T p.A1715S | Missense Mutation (SNP) | VAF 35/165 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.026); catalogued as COSV70199216; called by muse, mutect2, varscan2
- CCDC89 | c.346G>A p.G116S | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs1045327603, COSV57034030; called by muse, mutect2, varscan2
- CDC123 | c.325G>T p.A109S | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT tolerated (0.63); PolyPhen benign (0.045); catalogued as COSV55397654; called by muse, mutect2
- CDK17 | c.1010C>T p.A337V | Missense Mutation (SNP) | VAF 34/233 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54129045; called by muse, mutect2, varscan2
- CES5A | c.206C>T p.S69F | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.246); catalogued as rs1170954689, COSV51866330; called by muse, mutect2, varscan2
- CLINT1 | c.818C>A p.T273N | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.295); catalogued as COSV51624101; called by muse, mutect2, varscan2
- DDX25 | c.839C>T p.A280V | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.576); catalogued as COSV54990309; called by muse, mutect2
- FAM122C | c.89C>A p.A30D | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.106); catalogued as COSV66195277; called by muse, mutect2, varscan2
- GALK2 | c.1028T>C p.L343P | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.849); catalogued as COSV59101449; called by muse, mutect2, varscan2
- HJURP | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 24/193 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.021); catalogued as COSV64978775; called by muse, mutect2, varscan2
- HSPG2 | c.9052+1G>A p.X3018_splice | Splice Site (SNP) | VAF 13/86 reads (15%) | catalogued as rs1421561973, COSV101013430, COSV65932776, COSV65932908; called by muse, mutect2, varscan2
- IWS1 | c.1730T>G p.L577W | Missense Mutation (SNP) | VAF 25/178 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54868363; called by muse, mutect2, varscan2
- KDM5C | c.2189G>T p.C730F | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV64764953, COSV64768716; called by muse, mutect2, varscan2
- LRRK2 | c.4219C>A p.H1407N | Missense Mutation (SNP) | VAF 23/215 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); catalogued as COSV54153187; called by muse, mutect2, varscan2
- MTHFR | c.884G>T p.R295L | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.887); catalogued as COSV64877723, COSV64878950; called by muse, mutect2, varscan2
- MYL9 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 10/130 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.022); catalogued as rs775462736, COSV54072420; called by muse, mutect2
- NTSR1 | c.583G>A p.A195T | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV65138379; called by muse, mutect2, varscan2
- OR10W1 | c.598G>A p.V200M | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.167); catalogued as COSV67720443; called by muse, mutect2, varscan2
- OR5I1 | c.413T>G p.M138R | Missense Mutation (SNP) | VAF 20/97 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV56886926; called by muse, mutect2, varscan2
- PBRM1 | c.4284T>G p.Y1428* (on ENST00000296302 / NM_001366071.2; = p.Y1376* on NM_018313.5) | Nonsense Mutation (SNP) | VAF 116/552 reads (21%) | catalogued as COSV56276028; called by muse, mutect2, varscan2
- PKD1 | c.12253C>A p.L4085M (on ENST00000262304 / NM_001009944.3; = p.L4084M on NM_000296.4) | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.544); catalogued as CD1413116, COSV51916220; called by muse, mutect2, varscan2
- RBFOX1 | c.216C>A p.H72Q | Missense Mutation (SNP) | VAF 41/244 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.318); catalogued as COSV60958739; called by muse, mutect2, varscan2
- SDK2 | c.6106C>T p.L2036F | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.304); catalogued as COSV66185969; called by muse, varscan2
- SELE | c.1340C>T p.P447L | Missense Mutation (SNP) | VAF 33/221 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as rs1368355922, COSV60975397; called by muse, mutect2, varscan2
- SETD2 | c.5890G>T p.E1964* | Nonsense Mutation (SNP) | VAF 50/300 reads (17%) | catalogued as COSV57437697; called by muse, mutect2, varscan2
- SLC23A3 | c.424C>T p.L142F | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.419); catalogued as COSV55407224; called by muse, mutect2
- SLC9A4 | c.980+1G>A p.X327_splice | Splice Site (SNP) | VAF 26/200 reads (13%) | catalogued as rs754266683, COSV54829700; called by muse, mutect2, varscan2
- TNK1 | c.1762G>T p.D588Y (on ENST00000576812 / NM_001251902.2; = p.D583Y on NM_003985.5) | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs750427809, COSV61170464, COSV61170730; called by muse, mutect2, varscan2
- TPST1 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59177012; called by muse, mutect2, varscan2
- TPX2 | c.839A>C p.E280A | Missense Mutation (SNP) | VAF 17/224 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.296); catalogued as COSV55919612; called by muse, mutect2
- USP31 | c.3431C>A p.P1144H | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as COSV54852150; called by muse, mutect2, varscan2
- VWF | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 55/360 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as COSV54620347; called by muse, mutect2, varscan2
- YIF1B | c.335A>T p.Y112F (on ENST00000339413 / NM_001039673.3; = p.Y97F on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/311 reads (14%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.997); catalogued as COSV56650636; called by muse, mutect2, varscan2
- ZMYM4 | c.2681G>C p.S894T | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.017); catalogued as COSV58910477; called by muse, mutect2, varscan2
- ZNF572 | c.1442C>G p.A481G | Missense Mutation (SNP) | VAF 82/344 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV60001922; called by muse, mutect2, varscan2
- ABCC6 | c.4252del p.R1418Gfs*46 | Frame Shift Del (DEL) | VAF 7/57 reads (12%) | called by mutect2, pindel, varscan2
- NDUFAF6 | c.901del p.I301Ffs*40 | Frame Shift Del (DEL) | VAF 26/231 reads (11%) | called by mutect2, pindel, varscan2
- PROSER1 | c.2322del p.S775Lfs*174 | Frame Shift Del (DEL) | VAF 44/302 reads (15%) | called by mutect2, pindel, varscan2
- AGFG2 | c.1059C>T p.G353= | Silent (SNP) | VAF 8/64 reads (13%) | catalogued as rs146791629; called by mutect2, varscan2
- ALPK2 | c.5046A>G p.K1682= | Silent (SNP) | VAF 30/175 reads (17%) | catalogued as COSV64492991; called by muse, mutect2, varscan2
- BCL7A | c.471G>C p.S157= | Silent (SNP) | VAF 54/327 reads (17%) | catalogued as COSV55848352; called by muse, mutect2, varscan2
- GSPT2 | c.1416T>A p.V472= | Silent (SNP) | VAF 26/66 reads (39%) | catalogued as COSV61214348; called by muse, mutect2, varscan2
- LAMB2 | c.4422C>T p.L1474= | Silent (SNP) | VAF 8/97 reads (8%) | catalogued as rs779823135, COSV59733441; called by muse, mutect2
- PAX3 | c.1275G>T p.V425= | Silent (SNP) | VAF 12/86 reads (14%) | catalogued as COSV60588398; called by muse, mutect2
- PPFIA1 | c.3063T>C p.I1021= | Silent (SNP) | VAF 13/138 reads (9%) | catalogued as COSV54134534; called by muse, mutect2, varscan2
- TCHH | c.1594T>C p.L532= | Silent (SNP) | VAF 15/258 reads (6%) | catalogued as rs1384502361, COSV64274768; called by muse, mutect2
- UBE2O | c.2220C>T p.S740= | Silent (SNP) | VAF 44/314 reads (14%) | catalogued as COSV60063074; called by muse, mutect2, varscan2
- ZNF3 | c.1134C>G p.T378= | Silent (SNP) | VAF 23/243 reads (9%) | catalogued as COSV52795803; called by muse, mutect2
- AP000769.3 | chr11:65505838 A>G | 5'Flank (SNP) | VAF 31/192 reads (16%) | called by muse, mutect2, varscan2
- AP001425.1 | chr21:38208395 G>A | 5'Flank (SNP) | VAF 100/558 reads (18%) | called by muse, mutect2, varscan2
- FRMPD2B | n.1084C>A | RNA (SNP) | VAF 13/119 reads (11%) | called by mutect2, varscan2
- KIF1B | c.2115+6577G>T | Intron (SNP) | VAF 21/125 reads (17%) | catalogued as COSV55808687; called by muse, mutect2, varscan2
- SERPINB8 | c.*1A>G | 3'UTR (SNP) | VAF 28/145 reads (19%) | catalogued as rs769851296, COSV99728848; called by muse, mutect2, varscan2
